Surgical pathology report (de-identified scan), TCGA case TCGA-PE-A5DE, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Fox Chase, specimen TCGA-PE-A5DE-01A (Primary Tumor).

[page 1 of 4]
SPECIMEN:
SURGICAL PATHOLOGY REPORT

DOB:
Sex: F
Location:
Date Collected:
Date Received:
Physician:
Copy To:
Clinical History/Diagnosis: Left breast cancer

ICD-O-3
Carcinoma lobular
infiltrating NOS 8520/3
Site @ Breast NOS
C50.9
JW 5/24/13

Source of Specimen(s):
1: Sentinel Nodes-left axilla
2: left breast lumpectomy
3: Margin-final medial

Gross Description:
Received in three parts.
Source of Tissue: 1. Labeled # 1, "sentinel node left axilla"

Touch Preparation Evaluation: 1TP- NO TUMOR SEEN PER
(VERIFIED).

Gross Description: Received fresh for intraoperative consultation/touch impression in a container labeled "sentinel node left axilla". It consists of a tan to light brown rubbery lymph node measuring 1.6 x 1.3 x 1.0 cm. There is a stitch at one end marking the bluest portion. The node is sectioned. Touch impression of the bluest end was submitted as 1TPA and the tissue is subsequently submitted in 1A. Touch impression of the opposite end was submitted as 1TPB and subsequently the tissue is submitted in 1B.

Source of Tissue: 2. Labeled # 2, "left breast lumpectomy"

Gross Description: Received fresh in a container labeled "left breast lumpectomy". It consists of a 7.4 x 7.4 x 3.5 cm ovoid rubbery fragment of fibroadipose tissue. There is a short stitch marking the superior and a long marking the lateral. The anterior is inked blue and the remaining margins are inked black. The specimen is sectioned disclosing a large firm tan lesion with moderately defined borders measuring 3.8 x 2.6 x 1.9 cm. The lesion occupies an appreciable amount of the lumpectomy specimen. Laterally in the tumor there is inspissated blood consistent with previous biopsy site changes. The lesion comes very close to the medial, superior, and anterior resection margins. Also adjacently the breast parenchyma is fibrous and there is a 0.4 cm blue dome cyst noted. Representative sections are submitted in 2A-K.

[page 2 of 4]
Designation of Sections: 2A-2C- breast tissue with tumor in relationship to anterior margin, 2D-2F- breast tissue with tumor in relationship to posterior margin, 2G- additional sections of tumor, no margins are represented with biopsy site, 2H- perpendicular sections of superior resection margin, 2I- perpendicular sections of medial resection margin [Note: specimen 3 presumably supercedes this margin.], 2J- perpendicular sections of inferior margin, 2K- perpendicular sections of lateral margin

Source of Tissue: 3. Labeled # 3, "final medial margin"

Gross Description: Received fresh in a container labeled " final medial margin". It consists of a fragment of fibroadipose tissue measuring 2.5 x 2.0 x 1.0 cm. There is a stitch marking the final margin which is inked black prior to sectioning. Sections disclose no obvious residual lesional tissue. Entirely submitted in 3A and 3B.

Final Diagnosis:

1. Sentinel lymph node, left axilla, excision:
- One lymph node with no tumor seen (0/1).
- Negative immunohistochemical staining for cytokeratin AE1/AE3.
2. Left breast, lumpectomy:
- Invasive and in situ lobular carcinoma
- Invasive lobular carcinoma, 3.8 cm in greatest dimension grossly, grade II-III.
- Lobular carcinoma in situ, nuclear grade II-III, comprising approximately 5% of the tumor mass.
- Lymphovascular invasion is not identified.
- Invasive carcinoma is less than 1mm to the inked closest medial margin (see specimen 3 for final medial margin status), and remaining margins with no tumor seen.
- Changes consistent with prior biopsy site seen.
- Non-neoplastic breast tissue shows fibrocystic changes with microcalcifications.
3. Left breast, final medial margin, excision:
- Benign breast tissue, no tumor seen.

Note: Case reviewed with

who concurs with the

diagnosis.

[page 3 of 4]
Procedures/Addenda

Addendum Date Ordered: Status:
Date Complete: By:
Date Reported

Addendum Diagnosis
Specimen sent to for additional
testing.

Antibody/Tests	Results	Prognostic
Grouping		
DNA INDEX/PLOIDY	1.59	Aneuploid
S-Phase	See Below	
Ki-67 (MIB-1)	<10%	Favorable

An accurate S-phase fraction (SPF) value cannot be determined due to DNA aneuploid/tetraploid cell population <20% of total cells analyzed.

INVASIVE BREAST CANCER TEMPLATE: Excisions and Mastectomies

Specimen Type
Excision

Lymph Node Sampling
Sentinel lymph node only

Specimen Size (for excisions less than total mastectomy)
Greatest dimension: 7.4 cm

Laterality
Left

Tumor Site(s)
Not specified

Invasive Component
Solitary
Greatest dimension: 3.8 cm (grossly)

Histologic Type(s)
Lobular carcinoma in situ
Invasive lobular

[page 4 of 4]
Invasive Lobular Carcinoma Type
Classical, singet-ring, and pleomorphic

Invasion
Invasion confined to breast parenchyma

Angiolymphatic Invasion
Absent

Microcalcifications Associated with Carcinoma In Situ
No

Margins
Margins uninvolved by invasive carcinoma and in situ carcinoma

Regional Lymph Nodes
1 regional lymph node examined
No regional lymph node metastasis histologically and by
immunohistochemical staining for cytokeratin AE1/AE3 (N0)

Ancillary Immunopathology Studies (performed on
ER Positive
PR Positive
Her2-Neu Negative (score 0)

pTNM: T2 N0 Mx

Source: NCI Genomic Data Commons file 7b47bb17-79c2-4c61-8b91-00e312915557 (TCGA-PE-A5DE.6D2FA4DD-285F-4815-9494-76B297FA04AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).